Somatic mutation profile of tumor specimen TARGET-30-PAKHHB-01A (aliquot TARGET-30-PAKHHB-01A-01W) from TARGET case TARGET-30-PAKHHB, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of abdomen; Age at diagnosis: 1.9 years (687 days).
Specimen TARGET-30-PAKHHB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 520539c3-bd6a-49c1-837f-e42a99e0a5fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAKHHB-10A (Blood Derived Normal), aliquot TARGET-30-PAKHHB-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb08b9bf-4641-4f4c-a08f-f6823c4fac14

The open-access MAF lists 26 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 19, Silent 4, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP7A | c.3928G>A p.A1310T | Missense Mutation (SNP) | VAF 52/554 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58442433, COSV58447409; called by muse, mutect2
- CEP44 | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV56660513; called by muse, mutect2, varscan2
- COL28A1 | c.2842G>T p.E948* | Nonsense Mutation (SNP) | VAF 21/187 reads (11%) | catalogued as COSV101258922, COSV68084100; called by muse, mutect2, varscan2
- FLG2 | c.5860G>A p.G1954S | Missense Mutation (SNP) | VAF 397/1471 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761649223, COSV66172078; called by muse, mutect2, varscan2
- GLIS1 | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV56543467; called by muse, mutect2, varscan2
- GRIK5 | c.1489G>T p.V497L | Missense Mutation (SNP) | VAF 92/223 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as COSV53484346; called by muse, mutect2, varscan2
- HORMAD2 | c.425C>A p.T142K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.078); catalogued as COSV60900529; called by muse, mutect2, varscan2
- LRRC8B | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 203/281 reads (72%) | SIFT tolerated (0.77); PolyPhen benign (0.015); catalogued as COSV58376716; called by muse, mutect2, varscan2
- NALCN | c.3310G>T p.A1104S | Missense Mutation (SNP) | VAF 275/795 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV51959157; called by muse, mutect2, varscan2
- NPY5R | c.413T>G p.V138G | Missense Mutation (SNP) | VAF 94/201 reads (47%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.841); catalogued as COSV58453561; called by muse, mutect2, varscan2
- NYNRIN | c.3698C>A p.S1233Y | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV66844547; called by muse, mutect2, varscan2
- OR2T10 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 65/330 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57898075; called by muse, mutect2, varscan2
- PCSK1 | c.2072C>A p.A691E | Missense Mutation (SNP) | VAF 11/282 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60737082; called by muse, mutect2
- SIRT3 | c.793G>T p.G265W | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV66953671; called by mutect2, varscan2
- SLC4A1AP | c.1806G>T p.K602N | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100389166; called by muse, mutect2, varscan2
- TAF1L | c.4964C>A p.P1655Q | Missense Mutation (SNP) | VAF 250/553 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs975426723, COSV54267511; called by muse, mutect2, varscan2
- TDRD1 | c.3175G>T p.G1059* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as COSV52594870; called by mutect2, varscan2
- TTN | c.74201C>A p.S24734Y (on ENST00000591111; = p.S17310Y on NM_003319.4) | Missense Mutation (SNP) | VAF 16/462 reads (3%) | PolyPhen probably damaging (0.998); catalogued as COSV100628842; called by muse, mutect2
- ZNF264 | c.648C>A p.H216Q | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV54043382; called by muse, mutect2, varscan2
- CNTLN | c.1517A>C p.K506T | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, mutect2
- MAP2 | c.4278A>T p.R1426S | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); called by muse, mutect2
- ZBP1 | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- ABCA9 | c.3828C>T p.D1276= | Silent (SNP) | VAF 114/557 reads (20%) | catalogued as rs762426416, COSV60629831; called by muse, mutect2, varscan2
- ATAD2B | c.4239C>T p.N1413= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs191274942, COSV53204115; called by muse, mutect2, varscan2
- TEX45 | c.1338C>T p.F446= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV64464114; called by muse, mutect2, varscan2
- THNSL2 | c.300C>T p.N100= | Silent (SNP) | VAF 129/301 reads (43%) | catalogued as rs766842689, COSV59082021; called by muse, mutect2, varscan2
